Somatic mutation profile of tumor specimen TCGA-05-5423-01A (aliquot TCGA-05-5423-01A-01D-1625-08) from TCGA case TCGA-05-5423, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.3 years (23,863 days).
Specimen TCGA-05-5423-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4084a7-0ccd-4852-82a0-673c174fa444.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-5423-10A (Blood Derived Normal), aliquot TCGA-05-5423-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84191788-91d5-481d-b6d6-0d8b7600f357

The open-access MAF lists 157 somatic variants for this specimen: 125 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 30, Nonsense Mutation 10, RNA 2, Translation Start Site 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2499G>T p.L833F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51787416; called by muse, varscan2
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs1057519994, COSV52966960, COSV53427713, COSV99394424; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADCY10 | c.3683A>G p.K1228R | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as COSV63243777; called by muse, mutect2, varscan2
- ADGRB1 | c.1606G>C p.V536L | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV60101980; called by muse, mutect2, varscan2
- ADGRL3 | c.3010C>A p.Q1004K (on ENST00000506720 / NM_001322402.2; = p.Q936K on NM_015236.6) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.602); catalogued as COSV72229409, COSV72231556; called by muse, mutect2, varscan2
- ADNP | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62426507; called by muse, mutect2
- AHNAK2 | c.13530C>A p.D4510E | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.303); catalogued as COSV60925262; called by muse, varscan2
- AP3D1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs935169340, COSV61431665; called by muse, mutect2, varscan2
- ARHGAP12 | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs573378187, COSV60965445; called by muse, mutect2, varscan2
- AUTS2 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs772352925, COSV61423391; called by muse, mutect2, varscan2
- CACNA1E | c.3541G>C p.E1181Q | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV62411579; called by muse, mutect2, varscan2
- CACNA1H | c.4224G>T p.R1408S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV62000111; called by muse, mutect2, varscan2
- CASP2 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60081408; called by muse, mutect2, varscan2
- CCDC73 | c.857A>G p.H286R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs767694192, COSV58802925; called by muse, mutect2, varscan2
- CDH13 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562310269, COSV51829520, COSV51843504; called by muse, mutect2, varscan2
- CDH9 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50383850; called by muse, mutect2, varscan2
- CHD5 | c.3092A>T p.K1031M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52422188; called by muse, mutect2, varscan2
- CHD9 | c.2686A>G p.I896V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV54610506; called by muse, mutect2, varscan2
- COL5A2 | c.3581G>C p.G1194A | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66413300; called by muse, mutect2, varscan2
- CROCC | c.3224C>G p.S1075* | Nonsense Mutation (SNP) | VAF 15/118 reads (13%) | catalogued as COSV65014236; called by muse, mutect2, varscan2
- CSDE1 | c.1211G>T p.R404I (on ENST00000358528 / NM_001007553.3; = p.R373I on NM_007158.6) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54737955, COSV54742316; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs770705872, COSV54746208; called by muse, mutect2, varscan2
- CYB5B | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV57175214; called by muse, mutect2, varscan2
- CYB5R4 | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV63747093; called by muse, mutect2, varscan2
- DIPK2B | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV65005723; called by muse, mutect2, varscan2
- DMAC2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV99700492; called by muse, mutect2, varscan2
- DMXL1 | c.3206G>T p.R1069I | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as COSV60718812; called by muse, mutect2, varscan2
- DPF1 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100831470, COSV62792760; called by muse, mutect2, varscan2
- DPYD | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV64609964; called by muse, mutect2, varscan2
- E2F7 | c.862A>T p.R288* | Nonsense Mutation (SNP) | VAF 40/61 reads (66%) | catalogued as COSV59742536, COSV59744744; called by muse, mutect2, varscan2
- EGLN2 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100393705; called by muse, mutect2, varscan2
- FAM91A1 | c.2390A>G p.Q797R | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV58238848; called by muse, mutect2, varscan2
- FASTKD3 | c.1214C>G p.P405R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV52946056, COSV99242286; called by muse, mutect2, varscan2
- FAT3 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53156902, COSV53157273; called by muse, mutect2, varscan2
- FLT3 | c.1943-2A>T p.X648_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV54064746; called by muse, mutect2, varscan2
- GPR55 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101235810; called by muse, mutect2, varscan2
- GRIN2A | c.2167G>T p.G723W | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58050926; called by muse, mutect2, varscan2
- GRM6 | c.683G>C p.S228T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.593); catalogued as COSV51448016; called by muse, mutect2, varscan2
- HDAC9 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV67770600, COSV67781989; called by muse, mutect2, varscan2
- IARS2 | c.1870G>T p.G624* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as COSV56962801; called by muse, mutect2, varscan2
- IGF1R | c.2480C>A p.P827H | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51346055; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs201252363; called by muse, mutect2, varscan2
- KCNMB1 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV99210784; called by muse, mutect2, varscan2
- KEL | c.1196C>A p.P399Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV62337047; called by muse, mutect2, varscan2
- KIF26B | c.6020C>T p.A2007V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs770279217, COSV63648595; called by muse, mutect2
- KLHL4 | c.1078A>T p.R360W | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64145657; called by muse, mutect2, varscan2
- LAMB4 | c.2169C>G p.S723R | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV52727472; called by muse, mutect2, varscan2
- LDB3 | c.1421C>A p.S474* | Nonsense Mutation (SNP) | VAF 48/77 reads (62%) | catalogued as COSV53940850, COSV53947388; called by muse, mutect2, varscan2
- LIPI | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60714897; called by muse, mutect2, varscan2
- LMO7 | c.2953C>T p.Q985* (on ENST00000357063; = p.Q666* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58544455; called by muse, mutect2, varscan2
- LRRC66 | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV58635982; called by muse, mutect2, varscan2
- MADD | c.4610A>T p.K1537I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.901); catalogued as COSV60628502; called by muse, mutect2, varscan2
- MAP3K11 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1304044736, COSV58421223; called by muse, mutect2, varscan2
- MLNR | c.301T>C p.S101P | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as COSV99519810; called by muse, mutect2, varscan2
- MMD2 | c.553G>A p.E185K (on ENST00000404774 / NM_001100600.2; = p.E161K on NM_198403.4) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101286990; called by muse, mutect2
- MMP3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147533686; called by muse, mutect2, varscan2
- MOV10L1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as rs532990542, COSV53169936; called by muse, mutect2, varscan2
- MXRA5 | c.6889C>T p.R2297C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777337988, COSV54245677; called by muse, mutect2, varscan2
- MYBPC3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs397516045, COSV57032247; called by muse, mutect2, varscan2
- NDUFA9 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV56931201; called by muse, mutect2, varscan2
- NEFM | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1485845866, COSV55334284; called by muse, varscan2
- OR10J3 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766670052, COSV59955325; called by muse, mutect2, varscan2
- OR1F1 | c.779T>G p.F260C | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1305554544, COSV58962080; called by muse, mutect2, varscan2
- OR2A14 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV68718476; called by muse, mutect2, varscan2
- OR2T4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs756078095, COSV63544824; called by muse, mutect2, varscan2
- OR4C11 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs1343342588, COSV56354551; called by muse, mutect2, varscan2
- OR4C13 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV73648868, COSV73648981; called by muse, mutect2, varscan2
- OR4S2 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV56747919; called by muse, mutect2, varscan2
- OR8J1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); catalogued as COSV57319598; called by muse, mutect2, varscan2
- PCDHGA3 | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as COSV54005977; called by muse, mutect2, varscan2
- PCDHGA6 | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV54005993; called by muse, mutect2
- PCDHGA8 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.597); catalogued as COSV54006008, COSV99550366; called by muse, mutect2, varscan2
- PCLO | c.10766A>T p.D3589V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61657103; called by muse, mutect2, varscan2
- PDE10A | c.1610T>A p.M537K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63103320; called by muse, mutect2, varscan2
- PDGFRL | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV52414512; called by muse, mutect2
- PKD1L1 | c.368C>A p.A123E | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV56974427; called by muse, mutect2, varscan2
- POU2AF1 | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1448766634, COSV67577581; called by muse, mutect2, varscan2
- PSG8 | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs775456119, COSV60614435; called by muse, mutect2, varscan2
- PTPRK | c.2604G>T p.R868S (on ENST00000368215 / NM_001291984.2; = p.R869S on NM_002844.4) | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63904330; called by muse, mutect2, varscan2
- PTPRS | c.928A>T p.T310S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV53632103; called by muse, mutect2, varscan2
- RPS6KA5 | c.1687A>G p.I563V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.152); catalogued as COSV100002487; called by muse, mutect2, varscan2
- SAGE1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs782626692, COSV61016234; called by muse, varscan2
- SALL1 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746135021, COSV51755278; called by muse, mutect2, varscan2
- SALL1 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV51755268, COSV51757236; called by muse, mutect2, varscan2
- SALL1 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51762550; called by muse, mutect2, varscan2
- SEC24A | c.2986G>C p.V996L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV67306092; called by muse, varscan2
- SERPINB5 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV66975965; called by muse, mutect2, varscan2
- SETBP1 | c.4242G>T p.M1414I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV56332741; called by muse, mutect2, varscan2
- SGIP1 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.027); catalogued as COSV52776158; called by muse, mutect2, varscan2
- SHCBP1 | c.1276T>A p.C426S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.191); catalogued as COSV57649618; called by muse, mutect2, varscan2
- SIPA1L2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs776163837, COSV53396981; called by muse, mutect2, varscan2
- SLC10A1 | c.796T>G p.C266G | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53683546, COSV53683943; called by muse, mutect2, varscan2
- SLC25A37 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51565355, COSV99263895; called by muse, mutect2, varscan2
- SMG5 | c.2557A>T p.M853L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52746351; called by muse, mutect2, varscan2
- SOS2 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV99365935; called by muse, mutect2, varscan2
- SOWAHB | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57555030; called by muse, mutect2, varscan2
- SRGAP3 | c.2468C>A p.P823Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1403983614, COSV64537659; called by muse, mutect2, varscan2
- ST6GAL2 | c.1356C>A p.H452Q | Missense Mutation (SNP) | VAF 15/22 reads (68%) | PolyPhen probably damaging (0.962); catalogued as COSV62417677; called by muse, mutect2, varscan2
- STARD8 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52930713; called by muse, mutect2, varscan2
- STAU2 | c.295G>T p.E99* (on ENST00000524300 / NM_001164380.2; = p.E67* on NM_014393.2) | Nonsense Mutation (SNP) | VAF 48/64 reads (75%) | catalogued as COSV100869085; called by muse, mutect2, varscan2
- TAS2R1 | c.737T>A p.F246Y | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV101225750; called by muse, mutect2, varscan2
- TCHHL1 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as COSV64286978; called by muse, mutect2, varscan2
- TECPR2 | c.2627G>T p.C876F | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63973230; called by muse, mutect2, varscan2
- TEX14 | c.1520G>A p.R507Q (on ENST00000240361 / NM_001201457.2; = p.R501Q on NM_031272.5) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs368880555, COSV99541798; called by muse, mutect2, varscan2
- TMEM94 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as COSV58598912; called by muse, mutect2, varscan2
- TMOD1 | c.1015+1G>T p.X339_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV52251455; called by muse, mutect2, varscan2
- TNIK | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1407239423, COSV52691627; called by muse, mutect2, varscan2
- TRIL | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV100538798; called by muse, mutect2, varscan2
- TYK2 | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99314625; called by muse, mutect2, varscan2
- UNC5C | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as rs774497336, COSV71661513; called by muse, mutect2, varscan2
- URB2 | c.3796G>T p.A1266S | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.321); catalogued as COSV50981176; called by muse, mutect2, varscan2
- USH2A | c.14931G>T p.L4977F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1247695444, COSV56415478; called by muse, mutect2, varscan2
- USP25 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs754182220, COSV53488861; called by muse, mutect2, varscan2
- UTP20 | c.5924A>G p.D1975G | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55383157; called by muse, mutect2, varscan2
- XCL2 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV63194732; called by muse, mutect2, varscan2
- XRRA1 | c.866G>T p.S289I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV100369770; called by muse, mutect2, varscan2
- ZKSCAN2 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV60158238; called by muse, mutect2, varscan2
- ZNF416 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | catalogued as COSV52185440, COSV52185992; called by muse, mutect2, varscan2
- ZNF559 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs1468379209, COSV57836828; called by muse, mutect2, varscan2
- ZP4 | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV63913123; called by muse, mutect2, varscan2
- BIRC6 | c.3256dup p.W1086Lfs*3 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- GABRP | c.821G>T p.R274I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPDYE1 | c.284del p.P95Rfs*46 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- C2orf16 | c.5895C>A p.L1965= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs769942927, COSV62677527; called by muse, mutect2, varscan2
- CASKIN1 | c.3469C>A p.R1157= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100399416; called by muse, mutect2
- CCDC91 | c.1299A>T p.I433= | Silent (SNP) | VAF 56/90 reads (62%) | catalogued as COSV60346892; called by muse, mutect2, varscan2
- CTDSPL2 | c.837G>T p.P279= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV52947649, COSV99526582; called by muse, mutect2, varscan2
- DNAH2 | c.9408C>T p.N3136= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs200872109, COSV66723937; called by muse, mutect2, varscan2
- EDRF1 | c.1827A>T p.L609= (on ENST00000356792 / NM_001202438.2; = p.L575= on NM_015608.2) | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as COSV61764530, COSV61765684; called by muse, mutect2, varscan2
- EEF2K | c.219G>T p.G73= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV53785589; called by muse, mutect2, varscan2
- FCRL5 | c.639C>A p.T213= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as rs1184868150, COSV62518614; called by muse, mutect2, varscan2
- GPR55 | c.849G>T p.L283= | Silent (SNP) | VAF 59/99 reads (60%) | catalogued as COSV101235814; called by muse, mutect2, varscan2
- KRTAP5-6 | c.45G>T p.G15= | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as COSV101191731, COSV66289330; called by muse, varscan2
- MYLK3 | c.240G>T p.G80= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV67366059; called by muse, mutect2, varscan2
- NPY5R | c.402A>T p.S134= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV58453334; called by muse, mutect2, varscan2
- OR13A1 | c.108G>T p.S36= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV100980974, COSV65573108, COSV65573571; called by muse, mutect2, varscan2
- OR2G6 | c.12C>A p.T4= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100598116, COSV58573972; called by muse, mutect2, varscan2
- PDK3 | c.654G>T p.L218= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as COSV100998141; called by muse, mutect2, varscan2
- PLCB2 | c.3423G>A p.S1141= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs375249031; called by muse, mutect2, varscan2
- PLSCR5 | c.414G>A p.L138= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV71649170; called by muse, mutect2, varscan2
- PLVAP | c.255C>T p.T85= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV53086971; called by muse, mutect2, varscan2
- PRKDC | c.10224G>C p.G3408= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV58060372; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1614C>A p.R538= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs760338535, COSV57931834; called by muse, mutect2, varscan2
- SDF4 | c.372G>T p.T124= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV55420898; called by muse, mutect2, varscan2
- SLIT2 | c.4044C>T p.P1348= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV56579840; called by muse, mutect2, varscan2
- STAT5A | c.1071C>T p.G357= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as rs377400234; called by muse, mutect2, varscan2
- STAU2 | c.294G>T p.V98= (on ENST00000524300 / NM_001164380.2; = p.V66= on NM_014393.2) | Silent (SNP) | VAF 48/64 reads (75%) | catalogued as COSV100869087, COSV63311982; called by muse, mutect2, varscan2
- TLE1 | c.975C>T p.D325= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs780887683, COSV64691444; called by muse, mutect2, varscan2
- TLL2 | c.2865C>T p.D955= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs186470524; called by muse, mutect2, varscan2
- TLN1 | c.3477G>C p.L1159= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV59210582; called by muse, mutect2, varscan2
- TP53BP2 | c.963G>A p.K321= (on ENST00000343537 / NM_001031685.3; = p.K192= on NM_005426.2) | Silent (SNP) | VAF 49/359 reads (14%) | catalogued as COSV59071713; called by muse, mutect2, varscan2
- UBA6 | c.2571A>T p.G857= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV59180124; called by muse, mutect2, varscan2
- VHLL | c.45G>T p.A15= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV100372544; called by muse, mutect2, varscan2
- DENND10P1 | n.652C>A | RNA (SNP) | VAF 40/60 reads (67%) | called by muse, mutect2, varscan2
- SSPOP | n.3228G>C | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as COSV50488860; called by muse, mutect2, varscan2
